Somatic mutation profile of tumor specimen TCGA-HZ-8001-01A (aliquot TCGA-HZ-8001-01A-11D-2201-08) from TCGA case TCGA-HZ-8001, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 69.1 years (25,227 days).
Specimen TCGA-HZ-8001-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b9f3b4a-fba9-4db0-a5d0-6450ff987b57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8001-10A (Blood Derived Normal), aliquot TCGA-HZ-8001-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/430be64b-06dc-477b-9864-583a5920c184

The open-access MAF lists 47 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 39/467 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ACTG2 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100608897; called by muse, mutect2
- ADGRB2 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as COSV99925783; called by muse, mutect2
- ARID1A | c.5839C>T p.Q1947* | Nonsense Mutation (SNP) | VAF 44/1174 reads (4%) | catalogued as COSV61380856; called by muse, mutect2
- ATPAF1 | c.431T>A p.L144H (on ENST00000574428; = p.L167H on NM_022745.4) | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100236005; called by muse, mutect2
- ATR | c.6836A>C p.N2279T | Missense Mutation (SNP) | VAF 60/557 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100637724; called by muse, mutect2
- CCDC28B | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 28/512 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1475281610, COSV99356330; called by muse, mutect2
- DNAH10 | c.7156G>T p.D2386Y (on ENST00000409039; = p.D2325Y on NM_207437.3) | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101292021; called by muse, mutect2
- FBN2 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs528614556, COSV52495649; ClinVar: uncertain significance; called by muse, mutect2
- FSHR | c.1064C>A p.P355Q | Missense Mutation (SNP) | VAF 47/497 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58634736; called by muse, mutect2
- GALNT14 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 165/1866 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777768523, COSV61102293; called by muse, mutect2
- HELQ | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 50/974 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.661); catalogued as rs746323872, COSV99787441; called by muse, mutect2
- HS3ST2 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 27/711 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV99757698; called by muse, mutect2
- IRF7 | c.1006G>A p.A336T (on ENST00000397566; = p.A323T on NM_001572.5) | Missense Mutation (SNP) | VAF 35/655 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.068); catalogued as COSV99199577; called by muse, mutect2
- KLRC3 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs768046359, COSV101122914, COSV67251385; called by muse, mutect2
- LAMC1 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99279074; called by muse, mutect2
- MDGA1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 51/507 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs544453423, COSV99776393; called by muse, mutect2, varscan2
- MDGA2 | c.2534G>A p.R845K (on ENST00000399232 / NM_001113498.2; = p.R547K on NM_182830.4) | Missense Mutation (SNP) | VAF 25/626 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV100636475; called by muse, mutect2
- MED12L | c.6033G>A p.Q2011= | Splice Region (SNP) | VAF 38/456 reads (8%) | catalogued as COSV99851733; called by muse, mutect2
- NCBP2L | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs749697881, COSV100966483, COSV100966486; called by muse, mutect2, varscan2
- NLRP5 | c.2548A>C p.K850Q | Missense Mutation (SNP) | VAF 106/1369 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as COSV101173408; called by muse, mutect2
- NRK | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs753287534, COSV99686722; called by muse, mutect2, varscan2
- OBSCN | c.7664C>T p.A2555V | Missense Mutation (SNP) | VAF 51/556 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.191); catalogued as rs769945926, COSV52780087; called by muse, mutect2
- OR5L2 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 102/1240 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101004250, COSV65724490; called by muse, mutect2
- P2RY8 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.471); catalogued as COSV67177971; called by muse, mutect2
- PGM2 | c.1805C>A p.P602Q | Missense Mutation (SNP) | VAF 63/795 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1340087188, COSV101126541; called by muse, mutect2
- PRR27 | c.131T>C p.I44T | Missense Mutation (SNP) | VAF 63/1108 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.542); catalogued as COSV100748757; called by muse, mutect2
- PTGIS | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 43/422 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.093); catalogued as rs13306027, COSV99720705; called by muse, mutect2
- RECK | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 37/312 reads (12%) | catalogued as rs763497070, COSV100937425; called by muse, mutect2, varscan2
- SMARCE1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 51/646 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as CM1310768, COSV99228288; called by muse, mutect2
- STXBP1 | c.1499C>G p.P500R | Missense Mutation (SNP) | VAF 79/980 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100964527, COSV64812209; called by muse, mutect2
- TLR6 | c.221T>C p.F74S | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV101126242; called by muse, mutect2
- TRIP12 | c.3638C>T p.A1213V | Missense Mutation (SNP) | VAF 28/374 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.07); catalogued as COSV52264574, COSV99389472; called by muse, mutect2
- TTN | c.27741C>A p.Y9247* (on ENST00000591111; = p.Y8320* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/384 reads (7%) | catalogued as COSV100596684; called by muse, mutect2
- ZC2HC1C | c.488T>G p.V163G | Missense Mutation (SNP) | VAF 84/1098 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99472815; called by muse, mutect2
- ZNF721 | c.2637A>C p.K879N (on ENST00000338977; = p.K891N on NM_133474.4) | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV100167060; called by muse, mutect2
- ADAMTS5 | c.252C>T p.G84= | Silent (SNP) | VAF 26/615 reads (4%) | catalogued as rs1484169743, COSV53180058; called by muse, mutect2
- BTBD6 | c.1317C>T p.S439= | Silent (SNP) | VAF 69/770 reads (9%) | catalogued as rs1327047864, COSV59268031; called by muse, mutect2
- CNPY2 | c.366C>T p.G122= | Silent (SNP) | VAF 79/1296 reads (6%) | catalogued as COSV99836429; called by muse, mutect2
- ENAM | c.3309A>G p.E1103= | Silent (SNP) | VAF 45/520 reads (9%) | catalogued as COSV101252944; called by muse, mutect2
- GPI | c.480C>T p.S160= | Silent (SNP) | VAF 28/562 reads (5%) | catalogued as rs760767295, COSV62894526; called by muse, mutect2
- GPR179 | c.165G>A p.G55= | Silent (SNP) | VAF 17/516 reads (3%) | called by muse, mutect2
- PTPRD | c.2394C>T p.L798= | Silent (SNP) | VAF 86/801 reads (11%) | catalogued as COSV100643612; called by muse, mutect2, varscan2
- SFRP2 | c.396C>T p.F132= | Silent (SNP) | VAF 30/799 reads (4%) | catalogued as COSV56836953; called by muse, mutect2
- SLC10A2 | c.144C>T p.S48= | Silent (SNP) | VAF 36/1001 reads (4%) | catalogued as COSV99807671; called by muse, mutect2
- TRAV34 | c.318C>A p.I106= | Silent (SNP) | VAF 46/560 reads (8%) | called by muse, mutect2
- DEFB119 | c.61+1267C>T | Intron (SNP) | VAF 54/721 reads (7%) | catalogued as rs190164254, COSV59267138; called by muse, mutect2
